Gene-level copy-number profile of tumor specimen TCGA-66-2773-01A from TCGA case TCGA-66-2773, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.4 years (25,355 days).
Specimen TCGA-66-2773-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.6b550bb0-d432-4a7b-9e02-bbacc341764b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2773-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/594bc5ae-0fed-499a-ad56-e471c8f6c3a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,071; copy number 2: 23,751; copy number 3: 19,869; copy number 4: 11,633; copy number 5: 683; copy number 6: 1,728; copy number 7: 25; copy number 8: 1; copy number 12: 48; copy number 17: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2773-01A-01D-1195-01): tumor purity 0.41, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,490 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:240,014,348–248,919,946, 241 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:98,795,941–98,901,695, 1 gene, copy number 6 (within-gene range 4–6): DCBLD2.
- chr3:98,902,424–198,222,513, 1,727 genes, copy number 6 (broad region; genes not listed).
- chr5:58,198–29,217,115, 442 genes, copy number 5 (broad region; genes not listed).
- chr6:64,728,837–64,733,837, 1 gene, copy number 8: AL355357.1.
- chr10:50,305,586–52,755,507, 30 genes, copy number 7–17 (within-gene range 2–17): SGMS1, AC069547.2, AC069547.1, AL117341.1, RNU7-107P, SGMS1-AS1, SHQ1P1, BEND3P1, NUTM2HP, AL589794.1, CTSLP4, PGGT1BP1, AL589794.2, ASAH2B, A1CF, AL512366.1, CCDC58P2, AL731537.2, PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T, PRKG1-AS1, DKK1, RPL31P44, THAP12P3, LNCAROD.
- chr20:30,484,925–32,032,180, 48 genes, copy number 12: 5_8S_rRNA, AC018688.1, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L.

Autosomal genes at a single copy (total copy number 1): 805. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
